Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A2JQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A2JQ-01A (Primary Tumor).

Procurement Date: Laterality: Right

Path Report: THYROID CARCINOMA CHECKLIST

1. Tumor type: Papillary.
2. Tumor location: Right lobe.
3. Tumor multicentricity: Single focus
4. Tumor size: 2.1 x 1.9 cm.
5. Extrathyroid extension: Yes
6. Surgical margins: Free of tumor
7. Angiolymphatic invasion: Yes
8. Lymph nodes: 14 lymph nodes identified, 11 with metastatic papillary adenocarcinoma
9. TNM: T3 N1a Mx

100-0-3
Carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9
w 7/27/11

Source: NCI Genomic Data Commons file 184fcd10-dea2-4b6f-80d6-19711456476f (TCGA-E8-A2JQ.C1A33CCE-8C35-49E9-BE02-0E393F777674.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).